Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A4OZ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A4OZ-01A (Primary Tumor).

Gross Description: Skin flap of 7x4 cm in size, with mushroom-like tumor up to 2x1.8 cm in size. Seven dissected lymph nodes. Fragment of fatty tissue.

Microscopic Description: Malignant melanoma(pigmented)formed of nevus-like and spindle-like cells, without ulceration. Clark's level V. Breslow's depth 18 mm. Seven lymph nodes were examined, four lymph nodes proved metastatic. In the fatty tissue -- two lymph nodes with sclerosis. Fatty tissue -- without pathology changes, vascular hyperemia. According to ASCC 7-th Edition 4 or more metastatic nodes is stage N3.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: Subcutaneous tissue invaded (Clark's level V), Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.8 x 0 x 2 cm

Tumor features: Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: 4/7 positive for metastasis (Axillary 4/7)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Extent: Subcutaneous tissue invaded (Clark's level V)

Comments: Clark's level V. Breslow's depth 18 mm.

ICD-0-3

Melanoma, NOS 8720/3

Site: Skin, trunk C44.5

hw
10/5/12

Reviewed (initials)	10/11/12	10/14/12

Source: NCI Genomic Data Commons file 83056e36-0056-4fbb-b2d5-b0ac17b8df63 (TCGA-EB-A4OZ.4FBDBC67-99E1-4BB5-B713-34054272207A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).